TCGA case TCGA-V4-A9EH — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5e54122f-1c4d-45cc-8842-cd1c1df0eed8

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: France; Age at index: 53 years; Year of birth: 1958.

Diagnoses (1)
1. Spindle cell melanoma, NOS: ICD-O-3 morphology code: 8772/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Classification of tumor: primary; Age at diagnosis: 53.6 years (19,573 days); Year of diagnosis: 2012; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T4c; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIB; AJCC pathologic T: T4c; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 670 days (1.8 years); Sites of involvement: Eye, Choroid.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 22.
   Pathology details: Consistent pathology review: Yes; Extraocular nodule size: <=5mm; Extrascleral extension present: Yes; Measurement type: Echographic; Spindle cell percent range: >90%; Tumor depth measurement: 14; Tumor shape: Mushroom.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -7 days; Residual disease: R2; Treatment anatomic sites: Eye.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 78 days; Days to treatment end: 127 days; Treatment dose: 54 Gy; Number of fractions: 27; Treatment anatomic sites: Ocular Orbits.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 670 days (1.8 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 4.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg; Height: 169 cm; BMI: 28.
- Eye color: Brown.

Exposures
- Tobacco smoking status: Current Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V4-A9EH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 90 mg.
  Slide TCGA-V4-A9EH-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-V4-A9EH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9EH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology, Tumor morphology list, Tumor morphology: Histologic diagnosis: Spindle Cell; Tumor morphology percentage: >90%.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness measurement: Echographic Measurement.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 670 days; disease-specific survival: no event (censored), 670 days; progression-free interval: no event (censored), 670 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9EH-01A-11D-A39V-01): tumor purity 0.71, ploidy 2.09, whole-genome doublings 0.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- abnormality: Gain 20
- days to followup: 670
- days to outcome: 658
- days to procedure 1: -7
- diagnosis: melanoma
- disease status at last followup: No Evidence of Disease
- evaluated by imaging: no
- line of therapy 1: first
- m stage: M0
- morphologic subtype: spindle
- n stage: N0
- outcome: Stable Disease
- performance status scale: Karnofsky
- performance status score: 1
- radiation modality: EBRT
- radiation therapy anatomic site: orbit
- radiation therapy dose units: Gy
- resection status 1: R2
- smoking status: smoker
- staging system: AJCC
- t stage: T4c
- test methodology: aCGH
- test result: low risk
- unresectable 1: no
